Surgical pathology report (de-identified scan), TCGA case TCGA-61-1917, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1917-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OMENTUM, OMENTECTOMY -

METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA.

PART 2: LEFT ADNEXA, LEFT SALPINGO-OOPHORECTOMY -

- A. POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA OF LEFT OVARY.
- B. UNREMARKABLE LEFT FALLOPIAN TUBE.

PART 3: RIGHT ADNEXA, RIGHT SALPINGO-OOPHORECTOMY -

- A. POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA OF RIGHT OVARY.
- B. UNREMARKABLE RIGHT FALLOPIAN TUBE.

PART 4: UTERUS (400 GRAMS), TOTALLY ABDOMINAL HYSTERECTOMY -

- A. FOCAL SQUAMOUS ATYPIA, CHRONIC CERVICITIS AND SQUAMOUS METAPLASIA.
- B. ATROPHIC ENDOMETRIUM.
- C. UNREMARKABLE MYOMETRIUM.

PART 5: PELVIC ADHESIONS, EXCISION -

REACTIVE FIBROUS TISSUE WITH FOCAL METASTATIC ADENOCARCINOMA.

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

A. Laterality: 3

Right 2. Left 3. Bilateral

B. Procedure: 4

- 1. Cystectomy 4. TAH with salpingo-oophorectomy
- 2. Salpingo-oophorectomy 5. Other
- 3. Bilateral salpingo-oophorectomy

C. Tumor size (maximum dimension): 7.5 cm

D. Histologic type: 2

- | | |
|---------------------------------------|------------------------------------|
| 1. Papillary serous tumor, [REDACTED] | 12. Undifferentiated Carcinoma |
| 2. Papillary serous carcinoma | 13. Small cell carcinoma |
| 3. Mucinous tumor, [REDACTED] | 14. Mature teratoma |
| 4. Mucinous carcinoma | 15. Immature teratoma |
| 5. Endometrioid tumor, [REDACTED] | 16. Dysgerminoma |
| 6. Endometrioid carcinoma | 17. Embryonal carcinoma |
| 7. Clear cell tumor, [REDACTED] | 18. Yolk sac tumor |
| 8. Clear cell carcinoma | 19. Granulosa cell tumor, Juvenile |
| 9. Brenner tumor, [REDACTED] | 20. Granulosa cell tumor, adult |
| 10. Malignant Brenner tumor | 21. Malignant lymphoma |
| 11. Malignant mixed Müllerian tumor | 22. Others |

E. Histologic Grade: 3

- 1. Well 2. Moderate 3. Poorly differentiated

F. Vascular Invasion: 2

- 1. Yes 2. No

G. Tumor capsule: 1

- 1. Intact 2. Ruptured

H. Surface implants: 3

- 1. Invasive 2. Non-invasive 3. Not present

I. Surface implants:

- I1. Uterus: 2 1. Yes 2. No
- I2. Fallopian tubes: 2 1. Yes 2. No
- I3. Omentum: 1 1. Yes 2. No

I4. Peritoneal metastasis beyond the pelvis: 2

- 1. Microscopic 2. Less than 2 cms 3. More than 2 cms

J. Associated other lesion: na

- 1. Endometriosis.
- 2. Abnormalities of surface epithelium or surface epithelial inclusion.
- 3. Others.

K. Malignant cells in ascites or peritoneal washing: 2 1. Yes 2. No

L. Nodes Involved: na

L1. Number of positive lymph nodes: na

L2. Total number of lymph nodes examined: na

- | | | |
|---------------------|---------------------------|--------------------------|
| L3. Pelvic: | Right: # positive/total # | Left: # positive/total # |
| L4. Obturator: | Right: # positive/total # | Left: # positive/total # |
| L5. Common iliac: | Right: # positive/total # | Left: # positive/total # |
| L6. External iliac: | Right: # positive/total # | Left: # positive/total # |
| L7. Para-aortic: | Right: # positive/total # | Left: # positive/total # |
| L8. Inguinal: | Right: # positive/total # | Left: # positive/total # |

M. Extracapsular lymph node spread na 1. Yes 2. No

N. TNM Stage: T 3b N x M x

O. FIGO Stage: 3b

Source: NCI Genomic Data Commons file 16ac347b-a3d7-427b-87f9-5772915a24e8 (TCGA-61-1917.EBB81051-F181-4878-85AC-7E00AD6ACA85.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).